Somatic mutation profile of tumor specimen TCGA-EM-A2OV-01A (aliquot TCGA-EM-A2OV-01A-11D-A202-08) from TCGA case TCGA-EM-A2OV, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 64.8 years (23,656 days).
Specimen TCGA-EM-A2OV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ba8f535-5eae-426a-b7a8-e91203cafd8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2OV-10A (Blood Derived Normal), aliquot TCGA-EM-A2OV-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f640424-beea-4909-9cde-443efe573bdf

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCST2 | c.663G>A p.M221I | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.035); catalogued as rs772014989, COSV55054041; called by muse, mutect2
- EPHB1 | c.2461G>A p.G821R | Missense Mutation (SNP) | VAF 127/365 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67669173; called by muse, mutect2, varscan2
- EZH1 | c.1925A>T p.Y642F | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV70550424; called by muse, mutect2, varscan2
- FRY | c.7481G>A p.C2494Y | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.492); catalogued as rs1308257326, COSV66577534; called by muse, mutect2, varscan2
- GLP2R | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.432); catalogued as rs766910205, COSV52328713; called by muse, mutect2, varscan2
- PARD6B | c.433A>T p.I145F | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65405143; called by muse, mutect2, varscan2
- TET1 | c.4286T>C p.I1429T | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.135); catalogued as COSV65388607; called by muse, mutect2
- THOC1 | c.174T>G p.I58M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as rs760373126, COSV55277129; called by muse, mutect2, varscan2
- TM9SF4 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 76/222 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.591); catalogued as rs1223951369, COSV54110711; called by muse, mutect2, varscan2
- ZNF234 | c.1079A>G p.Q360R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV101468337, COSV70603549; called by muse, mutect2
- ARID2 | c.2178dup p.G727Rfs*5 | Frame Shift Ins (INS) | VAF 38/149 reads (26%) | called by mutect2, pindel, varscan2
- PLCE1 | c.1207-42870C>T | Intron (SNP) | VAF 62/170 reads (36%) | catalogued as COSV53349279, COSV53367522; called by muse, mutect2, varscan2
